Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3YE, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3YE-01A (Primary Tumor).

[page 1 of 3]
SurgPath Final
Temporary Copy

FINAL DIAGNOSIS

- A) Left thyroid lobe and isthmus, resection: Papillary thyroid carcinoma (3.5 cm), extending through the capsule into the perithyroidal soft tissues as well as focally into the attached skeletal muscle; the surgical margins are free; multiple (2 of 2) perithyroidal lymph nodes are both benign (synoptic report below).
- B) Right thyroid lobe, resection: Benign thyroid tissue.
- C) Central compartment lymph nodes, excision: One (of total 2) lymph node is involved by metastatic papillary thyroid carcinoma, without extranodal tumor extension. The specimen also includes benign thymic tissue with a parathyroid gland.

A: Thyroid Gland

HISTOLOGIC TYPE:

Papillary carcinoma
Classical (usual)

TUMOR FOCALITY:

Unifocal

ICD-O-3

Carcinoma, papillary, thyroid

8240/3

Site: thyroid, NOS
C73.9

TUMOR SIZE:

Greatest Dimension: 3.5 cm

6-7-12

R0

HISTOLOGIC GRADE:

G1: Well differentiated

PRIMARY TUMOR (pT):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

REGIONAL LYMPH NODES (pN):

pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes

NUMBER OF LYMPH NODE(S) INVOLVED: 1

NUMBER OF LYMPH NODE(S) EXAMINED: 4 (specimens A and C)

LYMPH NODE, EXTRANODAL EXTENSION:

Not identified

[page 2 of 3]
SurgPath Final
Temporary Copy

DISTANT METASTASIS (pM):
Not applicable

MARGINS:
Margins uninvolved by carcinoma
PERINEURAL INVASION:
Not identified
EXTRATHYROIDAL EXTENSION:
Present
Minimal

~electronic signature~

SPECIMEN RECEIVED

- A) LEFT THYROID LOBE AND ISTHMUS, FS
- B) RIGHT THYROID LOBE
- C) CENTRAL COMPARTMENT LYMPH NODES

FROZEN SECTION

A) Right thyroid lobe and isthmus, resection: Papillary thyroid carcinoma. Seen with

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "left thyroid lobe and isthmus" is a 12-gram lobe of thyroid with isthmus measuring overall approximately 4.5 x 2.8 x 2.4 cm. The capsule grossly appears intact. The specimen is inked on its surgical margins. Sectioning reveals an indurated brown/tan to tan nodule measuring approximately 3.5 cm in greatest dimension. Touch preps are made. Representative tissue is submitted for frozen section as A1-A2. The remainder of the specimen is submitted as A3-A10 for permanent sections. Tissue is also collected for the

B) In formalin labeled "right thyroid lobe". The specimen consists of a portion of dark purple/red thyroid tissue measuring 4.3 x 2.6 x 1.5 cm, 5.5 grams. The specimen is inked and serially sectioned revealing dark purple/red tissue. Representative sections are submitted in cassettes B1-B5.

[page 3 of 3]
C) In formalin labeled "central compartment lymph nodes". The specimen consists of an irregular portion of pink/tan to yellow/tan soft tissue measuring 1.5 x 1.5 x 0.8 cm. Multiple small lymph nodes are identified ranging in size from 0.3 up to 0.8 cm. The specimen is submitted entirely in cassette C1.

CLINICAL INFORMATION
LEFT THYROID NODULE

5/28/12

Source: NCI Genomic Data Commons file 0421d8ab-3537-455a-a4ac-1c358af8c2fd (TCGA-J8-A3YE.79B8945B-D78D-424C-BACE-32042C7D2D8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).